Surgical pathology report (de-identified scan), TCGA case TCGA-05-4244, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4244-01A (Primary Tumor).

Diagnosis:

1. Resection material from the right lower lobe of the lung with a peripheral, non-mucigenous, papillary adenocarcinoma, 4.5 cm in size, with foci of poor differentiation, with pleural infiltration and invasion of the blood vessels hilar lymph node metastases.

Tumor classification:

M-8140/3, G 3, pT 2, pV 0, pN 2, pMx, stage III A. R0.

Source: NCI Genomic Data Commons file 3da6d450-44cd-45d5-9384-f0b70492cef2 (TCGA-05-4244.3A844132-F813-4D8E-8F7D-DBAE0B23D7FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).